Somatic mutation profile of tumor specimen 6cb5d29a-9437-430d-b91c-57ee3d (aliquot 6cb5d29a-9437-430d-b91c-57ee3d_D6_1) from CPTAC case 09BR007, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.4 years (28,287 days).
Specimen 6cb5d29a-9437-430d-b91c-57ee3d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ea517f0-0b6c-4326-bf1d-274c91106300.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a86ecd9a-10fd-4eed-b246-12d587 (Blood Derived Normal), aliquot a86ecd9a-10fd-4eed-b246-12d587_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4234f264-9347-4325-8c9d-945ddb8f57bf

The open-access MAF lists 59 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Intron 6, 5'Flank 2, RNA 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.797T>G p.F266C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51644341, COSV51647202; called by mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 32/83 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C19orf18 | c.429G>T p.R143S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV58708135; called by muse, mutect2, varscan2
- CD14 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.369); catalogued as rs747248239; called by muse, mutect2
- CLEC14A | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.2); catalogued as rs755403608; called by muse, mutect2
- DNAH9 | c.7666G>A p.G2556R | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760880268, COSV99307734; called by muse, mutect2
- ERFE | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs770692551; called by muse, mutect2, varscan2
- HYDIN | c.10441C>T p.R3481W | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs76078590, COSV101154480; called by muse, mutect2, varscan2
- IGKV1-12 | c.345T>A p.S115R | Missense Mutation (SNP) | VAF 151/967 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1252011745; called by mutect2, varscan2
- LHCGR | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV54292012; called by muse, mutect2
- NXF3 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV101221910; called by muse, mutect2, varscan2
- PSMB8 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100841283; called by muse, mutect2
- RAD50 | c.1513A>G p.I505V | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs193921012, COSV54749200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs750399038; called by muse, mutect2, varscan2
- TDP1 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs750187948, COSV59644418; called by muse, mutect2
- TMEM30B | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1394624975; called by muse, mutect2, varscan2
- VRTN | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs138257884, COSV104373863; called by muse, mutect2, varscan2
- ZNF107 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV61328125; called by muse, mutect2
- AGPAT1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 178/682 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CCDC168 | c.14615A>G p.K4872R | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CD27 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CKAP2L | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.4372C>T p.H1458Y | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DEPDC1 | c.1367T>C p.F456S | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.14236G>C p.D4746H | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- IGLV5-37 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRG1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 53/527 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MTOR | c.7384G>A p.E2462K | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- MUC16 | c.43035_43036del p.N14345Kfs*9 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- NDRG1 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 66/394 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- OR51I1 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 30/366 reads (8%) | called by muse, mutect2
- PTGS2 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2
- SRPX | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2
- STAB2 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENM3 | c.4277T>A p.I1426N | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- USF3 | c.4571A>G p.K1524R | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF540 | c.904A>C p.K302Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- COL18A1 | c.2352G>A p.P784= (on ENST00000359759 / NM_130444.3; = p.P549= on NM_030582.4) | Silent (SNP) | VAF 15/268 reads (6%) | catalogued as rs536257333, COSV62700548; called by muse, mutect2
- CYP2R1 | c.186C>T p.P62= | Silent (SNP) | VAF 62/361 reads (17%) | catalogued as rs782434537; called by muse, mutect2, varscan2
- DIO3 | c.303C>T p.C101= | Silent (SNP) | VAF 38/395 reads (10%) | catalogued as COSV63773856; called by muse, mutect2
- FSCN2 | c.834C>T p.N278= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as rs575229153, COSV58367629; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1491C>T p.A497= | Silent (SNP) | VAF 64/195 reads (33%) | called by mutect2, varscan2
- KCNJ15 | c.84C>T p.R28= | Silent (SNP) | VAF 27/278 reads (10%) | catalogued as rs145800740; called by muse, mutect2
- PRSS56 | c.1611C>T p.S537= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs971066079; called by muse, mutect2
- PTCHD4 | c.1461C>T p.D487= | Silent (SNP) | VAF 47/322 reads (15%) | catalogued as rs528743841, COSV59788674; called by muse, mutect2, varscan2
- RAB39B | c.564G>A p.G188= | Silent (SNP) | VAF 34/335 reads (10%) | called by muse, mutect2
- RELN | c.10176C>T p.V3392= | Silent (SNP) | VAF 30/508 reads (6%) | called by muse, mutect2
- SALL3 | c.3073C>T p.L1025= | Silent (SNP) | VAF 32/436 reads (7%) | called by muse, mutect2
- AC244517.10 | c.36-4958C>T | Intron (SNP) | VAF 12/272 reads (4%) | called by muse, mutect2
- BRWD1 | chr21:39314021 del CCGCAGGGGCCCCGAGT | 5'Flank (DEL) | VAF 28/97 reads (29%) | called by mutect2, varscan2
- CYS1 | chr2:10083938 G>T | 5'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- FAM86C1P | n.148C>A | RNA (SNP) | VAF 27/170 reads (16%) | catalogued as COSV100660773; called by muse, mutect2, varscan2
- LINC02381 | n.88A>C | RNA (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2
- LYPD3 | c.382+25G>T | Intron (SNP) | VAF 13/328 reads (4%) | called by muse, mutect2
- MED24 | c.2624-10C>T | Intron (SNP) | VAF 22/150 reads (15%) | catalogued as rs112526586; called by muse, mutect2, varscan2
- MOCS1 | c.*1058T>A | 3'UTR (SNP) | VAF 18/646 reads (3%) | called by muse, mutect2
- SLX4 | c.951-36G>A | Intron (SNP) | VAF 74/435 reads (17%) | catalogued as rs756211902; called by muse, mutect2, varscan2
- SUMO1 | c.238-574C>A | Intron (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- UTP18 | c.1328+1153C>T | Intron (SNP) | VAF 16/225 reads (7%) | catalogued as rs1331490752; called by muse, mutect2
